Surgical pathology report (de-identified scan), TCGA case TCGA-50-8459, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-8459-01A (Primary Tumor).

[page 1 of 4]
FINAL DIAGNOSIS:

Collection Date: [REDACTED]

Summary Statement

The right lower lobectomy reveals a 7.5 cm, moderately differentiated mucinous adenocarcinoma with angiolymphatic and visceral pleural invasion with no involvement of N1 or N2 lymph nodes and free margins. Pathologic stage: T3 N0.

PART 1: BONE, RIGHT SIXTH RIB, PARTIAL RESECTION –

SPECIMEN UNDERGOING DECALCIFICATION. ADDENDUM REPORT TO FOLLOW.

PART 2: LYMPH NODE, LEVEL 9 LYMPH NODE NEAR RIGHT INFERIOR LIGAMENT, BIOPSY –

SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 3: LYMPH NODE, SUBCARINAL PACKET, BIOPSY –

FOUR FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 4: LYMPH NODE, SUBCARINAL NEAR MAIN BRONCHUS, BIOPSY –

TWO FRAGMENT OF LYMPH NODE WITH REACTIVE CHANGE INCLUDING ANTHRACOSILICOTIC NODULES WITH NECROSIS. NO EVIDENCE OF MALIGNANCY.

PART 5: LYMPH NODE, LEVEL 12 "LYMPH NODE NEAR FISSURE", BIOPSY –

TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 6: LYMPH NODE, "LYMPH NODE NEAR MIDDLE LOBE ARTERY", BIOPSY –

TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 7: LYMPH NODE, "LYMPH NODE NEAR FISSURE", BIOPSY –

FIVE FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 8: LYMPH NODE, "LYMPH NODE NEAR MIDDLE LOBE BRONCHUS", BIOPSY –

TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 9: LYMPH NODE, "LYMPH NODE NEAR MIDDLE LOBE VEIN", BIOPSY –

THREE FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 10: LYMPH NODE, "LYMPH NODE NEAR BRONCHUS INTERMEDIUS", BIOPSY –

SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 11: LYMPH NODE, "LEVEL 11 LYMPH NODE NEAR VASTUS OF MIDDLE LOBE VEIN", BIOPSY –

TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 12: SOFT TISSUE, "TISSUE NEAR FISSURE", BIOPSY –

FRAGMENTS OF BENIGN FIBROADIPOSE TISSUE.

PART 13: LYMPH NODE, "FISSURE LYMPH NODE NEAR SUPERIOR SEGMENT BRONCHUS", BIOPSY –

- A. TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE WITH FOCAL GRANULOMATOUS REACTION TO FOREIGN MATERIAL. GROCOTT AND ACID FAST STAINS FOR MICROORGANISMS ARE NEGATIVE. CORRELATION WITH CULTURE RESULTS SUGGESTED.
- B. NO EVIDENCE OF MALIGNANCY.

PART 14: LYMPH NODE, "LEVEL 11 LYMPH NODE NEAR BASILAR BRONCHUS", BIOPSY –

THREE FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 15: LUNG, RIGHT LOWER LOBE, LOBECTOMY –

- A. INVASIVE MODERATELY DIFFERENTIATED MUCINOUS ADENOCARCINOMA, DIAMETER 7.5 CM, WITH VISCERAL PLEURAL AND ANGIOLYMPHATIC INVASION. ALL MARGINS FREE. MILD HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE: T3 N0.
- B. TEN LOBAR LYMPH NODES WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.
- C. MILD EMPHYSEMATOUS CHANGE.

COMMENT:

The invasive moderately differentiated mucinous adenocarcinoma shows a variety of architectural patterns with lepidic and papillary patterns predominant, although the areas of invasion show the predominance of acinar growth. Multiple small satellite lesions are seen within 1 cm of the main tumor mass and representative sectioning of the remainder of the lobe fails to show gross satellite nodules.

PAS, PAS-D and mucicarmine stains are strongly positive in the neoplastic cells. VVG stains show visceral pleural invasion (D Block). Immunoperoxidase stains show that the tumor cells are negative for p63 and cytokeratin 5/6 and fail to express TTF-1.

[page 2 of 4]
Grocott and acid-fast stains are negative.

Sections of the part 1 "right sixth rib" show normal bone and bone marrow with trilineage representation and maturation. No evidence of malignancy is seen.

COMPREHENSIVE THERANOSTIC SUMMARY

IMMUNOHISTOCHEMISTRY

IN SITU HYBRIDIZATION / FISH

ALK rearrangement:

NEGATIVE

C-MET amplification:

NEGATIVE

MOLECULAR ANATOMIC PATHOLOGY

EGFR exon 18 mutation:

NEGATIVE

EGFR exon 19 mutation:

NEGATIVE

EGFR exon 20 mutation:

NEGATIVE

EGFR exon 21 mutation:

NEGATIVE

BRAF exon 15 mutation (PCR):

NEGATIVE

KRAS exon 2 (codons 12, 13) mutation (PCR):

POSITIVE (mutation type: p.G12C)

KRAS exon 3 (codon 61) mutation (PCR):

NEGATIVE

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION:

Right Lower Lobe

PROCEDURE:

Lobectomy

TUMOR SIZE:

Maximum dimension: 7.5 cm

Minor dimension: 7.0 cm

GROSS SATELLITES:

Number of gross satellite lesions: 0

TUMOR TYPE:

Invasive adenocarcinoma, Dominant Pattern: Mucinous

HISTOLOGIC GRADE:

G2, Moderately differentiated

MICROSCOPIC "SATELLITES"/METASTASES:

Number of microscopic lesions: 0

EXTRAPULMONARY EXTENSION/INVASION OF TUMOR:

Visceral pleura (PL1)

ANGIOLYMPHATIC INVASION:

Yes

TUMOR NECROSIS:

< or = to 50%

SURGICAL MARGIN INVOLVEMENT:

No

SURGICAL MARGIN SITE:

Distance of invasive tumor to closest margin: 15 mm, Bronchial margin

INFLAMMATORY(DESMOPLASTIC) REACTION:

Mild

N1 LYMPH NODES:

Number of N1 lymph nodes positive: 0

Number of N1 lymph nodes examined: 25

N2 LYMPH NODES:

Number of N2 lymph nodes positive: 0

Number of N2 lymph nodes examined: 7

UNDERLYING DISEASE(S):

Emphysema

T STAGE, PATHOLOGIC:

pT3

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

Not applicable

ANCILLARY STUDIES:

Histochemical stains, Immunohistochemical stains, FISH studies, Molecular studies

In Situ Procedure

Interpretation

Probe: ROS Dual-Color Break-apart Probe 6p22.1

Probe Description: The two probes are overlapped by approximate 60kb

ROS1 FISH STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE FOR TRANSLOCATION.

of cells analyzed: 67

% cells positive for translocation: 0(0%)

% cells negative for translocation: 67(100%)

Results

ROS Methodology Description:

ROS translocation detection is as follows: Normal cells without the ROS translocation show green and red signals in juxtaposition. Cells with the ROS translocation show one pair of signals (green and red) in juxtaposition and one green and one red signal separated.

ROS FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the ROS Texas Red (centromeric) and the ROS FITC(telomeric) probes.

[page 3 of 4]
SPECIAL PROCEDURES:
Molecular Anatomic Pathology Procedure
Interpretation

MOLECULAR ANATOMIC PATHOLOGY TESTING:

Block 15C:

- A. *KRAS* codon 12 mutation IDENTIFIED (p.G12C, c.34G>T).
- B. *KRAS* codon 61 mutation NOT identified.
- C. *EGFR* exon 18 mutation NOT identified.
- D. *EGFR* exon 19 mutation NOT identified.
- E. *EGFR* exon 20 mutation NOT identified.
- F. *EGFR* exon 21 mutation NOT identified.
- G. *BRAF* codon 600 mutation NOT identified.

NOTE:

The quantity and quality of isolated DNA was acceptable for testing.

BACKGROUND:

EGFR mutations are present in about 10-15% of non-Asian and up to 40% of the Asian patients with non-small-cell lung cancer (NSCLC) (1,2). They are more frequent in non-smokers, females, and in tumors with adenocarcinoma histology. Activating *EGFR* mutations including exon 19 deletions, exon 21 point mutations (L858R, L861Q), and exon 18 G719A/C/S point mutation are associated with the clinical response to treatment with *EGFR* tyrosine kinase inhibitors (TKI) (gefitinib, erlotinib) (2-4). Advanced NSCLC patients with activating *EGFR* mutations show response rates of more than 70%, with progression-free survival up to 14 month (2,3). However, *EGFR* mutations in exon 20 (insertions and T790M point mutation) are associated with acquired resistance to TKIs (4). *KRAS* mutations and *BRAF* mutations are found in approximately 30% and 2% of lung adenocarcinomas respectively. The most common mutation types are *KRAS* codon 12/13 and *BRAF* V600E. Patients with these mutations tend to be resistant to erlotinib and gefitinib (2,5,6). However, not all tumors reveal such a correlation and, therefore, the results of molecular testing should be interpreted in conjunction with other laboratory and clinical findings.

MUTATIONAL ANALYSIS:

For cytology samples, extraction of DNA was performed from the fluid or sample provided. For surgical specimens, manual microdissection was performed. Specimens with the minimum of 50% of tumor cells in a microdissection target or more than 300 cells for FNA specimen were accepted for the analysis. DNA was isolated using standard laboratory procedure. Optical density readings were obtained. For the detection of mutation, DNA was amplified with primers for the exons 2 and 3 of the KRAS gene and exons 18-21 of the EGFR gene. Then, forward and reverse sequencing was performed using the BigDye Terminator Kit on ABI3130. The sequencing electropherograms were analyzed for the presence of mutations. The method sensitivity is approximately 20% of mutant alleles in a background of normal DNA. For detection of BRAF mutation, real-time PCR was performed on the LightCycler platform to amplify BRAF codons 599-601 sequences. Post-PCR melting curve analysis was used to detect possible mutations. If required, the mutation type was confirmed by Sanger sequencing of the PCR product on ABI3130. The limit of detection is approximately 10-20% of alleles with mutation present in the background of normal DNA.

In Situ Procedure

Interpretation

PROBE: LSI *ALK* Dual-Color Break-apart Probe 2p23

***ALK* FISH STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE.**

[page 4 of 4]
Number of cells analyzed: 61

% of cells positive for the *ALK* rearrangement: 0%

Only split O & G (single O and single G in the same nucleus): 0%

Fusion + split O and G in the same nucleus: 0%

Only single O: 0%

Fusion + single O: 0%

% of the cells with the normal pattern: 61(100%)

ALK FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the *ALK* SpectrumOrange (telomeric) and the *ALK* SpectrumGreen (centromeric) probes.

PROBE: *c-MET/*CEP7***

Cytogenetic Location: 7q31.2 / 7p11.1-q11.1

***C-MET* FISH STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE FOR AMPLIFICATION.**

Number of cells analyzed: 60

Ratio *c-MET*/*CEP7*: 1.05

SNR (signal to nucleus ratio): 1.9

CNR (centromere to nucleus ratio): 1.8

Results

ALK translocation is detected as follows:

ALK negative:

0-15% of cells positive for the *ALK* rearrangement.

Normal cells without the *ALK* translocation show green and orange signals in juxtaposition.

ALK positive:

Greater than 15% of cells positive for the *ALK* rearrangement.

Cells with the *ALK* translocation show one of the following patterns: One pair of signals (green and orange) fused or in juxtaposition and one green and one orange signal separated; Only split O & G (single O and single G in the same nucleus); Only single O; Fusion + single O.

c-MET amplification is detected as follows:

*RP11-163C9 [REDACTED] EP7 [REDACTED]

c-MET FISH positive:

Gene Amplification: Ratio gene/chromosome more than two

c-MET FISH negative:

Ratio gene/chromosome less than two

Source: NCI Genomic Data Commons file b691721a-55dc-4d4b-9b96-11d5df84b972 (TCGA-50-8459.BE87241C-FCB4-416F-A8A4-74B09033CA0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).